Somatic mutation profile of tumor specimen 0DSHT6 from CCDI case PBCIEF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.3 years (2,664 days).
Specimen 0DSHT6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 826bffd1-c9ba-4a5e-9902-c1ccc3d307fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSHTH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6443d227-f7b7-445b-ba86-c24c262a823c

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 40/526 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs767063127, COSV63754561; called by muse, mutect2
- EN2 | c.674G>C p.R225P | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52083392; called by muse, mutect2
- FAM110A | c.187C>G p.R63G | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs867123388; called by muse, mutect2
- PTCHD1 | c.1123T>A p.F375I | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
